Somatic mutation profile of tumor specimen TCGA-46-6026-01A (aliquot TCGA-46-6026-01A-11D-1817-08) from TCGA case TCGA-46-6026, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 81.8 years (29,890 days).
Specimen TCGA-46-6026-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 608645c8-c45f-4b01-9f51-2960df53f325.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-46-6026-10A (Blood Derived Normal), aliquot TCGA-46-6026-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09c9847b-4e6a-42da-afc8-46445895284b

The open-access MAF lists 229 somatic variants for this specimen: 175 protein-altering or splice-affecting, 48 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 48, Nonsense Mutation 9, Frame Shift Del 7, Splice Site 4, 5'UTR 3, In Frame Del 2, Frame Shift Ins 2, Nonstop Mutation 2, RNA 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SETD2 | c.4874G>A p.R1625H | Missense Mutation (SNP) | VAF 77/95 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57431794, COSV57438402; called by muse, mutect2, varscan2
- TP53 | c.754_762del p.L252_I254del | In Frame Del (DEL) | VAF 47/58 reads (81%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AC091959.1 | c.3049G>T p.A1017S | Missense Mutation (SNP) | VAF 42/52 reads (81%) | catalogued as COSV57944159; called by muse, mutect2, varscan2
- AKAP13 | c.1399G>A p.G467S | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV63463532; called by muse, mutect2, varscan2
- ALDH1A2 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV51084795; called by muse, mutect2, varscan2
- ANKRD53 | c.649C>A p.L217M | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); catalogued as COSV55538069; called by muse, mutect2, varscan2
- ANKS1B | c.1482C>A p.N494K | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV61361079; called by muse, mutect2, varscan2
- ANO4 | c.2417G>T p.G806V (on ENST00000392977 / NM_001286615.2; = p.G771V on NM_178826.4) | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54603162; called by muse, mutect2, varscan2
- AOC2 | c.1351A>G p.S451G | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV53199899; called by muse, mutect2, varscan2
- AQP8 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); catalogued as COSV54845177; called by muse, mutect2, varscan2
- ARFGEF1 | c.2042C>T p.T681I | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.091); catalogued as COSV51612098; called by muse, mutect2, varscan2
- ASIC1 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0.086); catalogued as rs373616682; called by muse, mutect2, varscan2
- ASPM | c.6015G>T p.R2005S | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54133227; called by muse, mutect2, varscan2
- ATP1A2 | c.1103C>T p.T368M | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746383817, CM105887, COSV63402315; called by muse, mutect2, varscan2
- BLK | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV52049720, COSV52053766; called by muse, mutect2, varscan2
- CACNA1C | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756273121, COSV59694699; called by muse, mutect2, varscan2
- CACNA2D1 | c.1144G>T p.V382L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV62373259; called by muse, mutect2, varscan2
- CADM2 | c.1030C>A p.P344T (on ENST00000407528 / NM_001167674.2; = p.P346T on NM_153184.4) | Missense Mutation (SNP) | VAF 181/206 reads (88%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV67387297; called by muse, mutect2, varscan2
- CAPS2 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60826809; called by muse, mutect2, varscan2
- CBL | c.1407G>A p.M469I | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV50645597; called by muse, mutect2, varscan2
- CCDC15 | c.2344A>G p.M782V | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV61083199; called by muse, mutect2, varscan2
- CCDC38 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 117/217 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs142050445; called by muse, mutect2, varscan2
- CCDC74B | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.403); catalogued as COSV100134535; called by muse, mutect2, varscan2
- CCDC93 | c.215T>C p.L72S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60122484; called by muse, mutect2, varscan2
- CDH12 | c.647-2A>T p.X216_splice | Splice Site (SNP) | VAF 36/132 reads (27%) | catalogued as COSV66421867; called by muse, mutect2, varscan2
- CDH17 | c.163C>G p.P55A | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV50327467, COSV50332328; called by muse, mutect2, varscan2
- CELSR1 | c.2744C>G p.S915C | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53094112; called by muse, varscan2
- CFAP45 | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV63649939; called by muse, mutect2, varscan2
- CHRD | c.1078G>T p.A360S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52609865; called by muse, mutect2
- CHRM2 | c.1243C>A p.P415T | Missense Mutation (SNP) | VAF 93/154 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV57777272; called by muse, mutect2, varscan2
- COMMD10 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 56/69 reads (81%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV57238582; called by muse, mutect2, varscan2
- CPS1 | c.2075G>A p.G692D | Missense Mutation (SNP) | VAF 67/111 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV51816009; called by muse, mutect2, varscan2
- CPSF1 | c.3835A>G p.M1279V | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1225375257, COSV58234430; called by muse, mutect2, varscan2
- CUL5 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as COSV67609456; called by muse, varscan2
- CYP26B1 | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as COSV50012971; called by muse, mutect2, varscan2
- DCLK1 | c.431A>G p.K144R | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV55195853, COSV99709434; called by muse, mutect2, varscan2
- DEFB114 | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as COSV59038193; called by muse, mutect2, varscan2
- DNAH1 | c.6970G>A p.D2324N | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs748004643, COSV70231803; called by muse, mutect2, varscan2
- DOCK10 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); catalogued as COSV51376443; called by muse, mutect2, varscan2
- DOCK2 | c.3884A>C p.E1295A | Missense Mutation (SNP) | VAF 43/54 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV56970432, COSV56990534; called by muse, mutect2, varscan2
- DST | c.20104G>A p.E6702K (on ENST00000361203 / NM_001374722.1; = p.E4399K on NM_015548.5) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55025115; called by muse, mutect2, varscan2
- DST | c.3044G>A p.R1015H (on ENST00000361203 / NM_001374722.1; = p.R689H on NM_001723.6) | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1003908769, COSV55025131; called by muse, mutect2, varscan2
- DTNA | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs746246245, COSV52012837; called by muse, mutect2, varscan2
- EARS2 | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV71942900; called by muse, mutect2, varscan2
- ELMO1 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 66/91 reads (73%) | SIFT tolerated (0.14); PolyPhen benign (0.401); catalogued as COSV60312460, COSV60331739; called by muse, mutect2, varscan2
- ELOVL3 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199876592, COSV64174566; called by muse, mutect2, varscan2
- ENPP2 | c.377C>G p.A126G | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as COSV50021915; called by muse, mutect2, varscan2
- EP400 | c.6826G>T p.V2276F | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as COSV57777871; called by muse, mutect2, varscan2
- EPB41 | c.1414G>T p.A472S (on ENST00000343067 / NM_001166005.2; = p.A263S on NM_004437.4) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV58050213; called by muse, mutect2, varscan2
- EPRS1 | c.70G>T p.V24L | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV65100122; called by muse, mutect2, varscan2
- ERI1 | c.499-1G>T p.X167_splice | Splice Site (SNP) | VAF 85/186 reads (46%) | catalogued as COSV51571943; called by muse, mutect2, varscan2
- ESRRB | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746745430, COSV55063700, COSV99063228; called by muse, mutect2, varscan2
- FAM126A | c.197G>T p.S66I | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV69017319; called by muse, mutect2, varscan2
- FARSA | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs376853642, COSV58905320; called by muse, mutect2, varscan2
- FAT3 | c.11827G>T p.A3943S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.758); catalogued as COSV99967136; called by muse, mutect2
- FBN2 | c.1598G>T p.C533F | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52526595; called by muse, mutect2, varscan2
- FGA | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs139005577; called by muse, mutect2, varscan2
- FGF10 | c.5G>C p.W2S | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs199671312, COSV52936591; called by muse, mutect2, varscan2
- FHDC1 | c.3307G>T p.E1103* | Nonsense Mutation (SNP) | VAF 11/19 reads (58%) | catalogued as COSV52601278; called by muse, mutect2, varscan2
- FLG | c.2344C>T p.R782W | Missense Mutation (SNP) | VAF 138/404 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs558836936, COSV64238446, COSV64241098; called by muse, mutect2, varscan2
- FLG2 | c.2942C>A p.S981* | Nonsense Mutation (SNP) | VAF 187/302 reads (62%) | catalogued as COSV66170410; called by muse, mutect2, varscan2
- FNIP1 | c.1588G>T p.D530Y | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV57198059; called by muse, mutect2, varscan2
- FOCAD | c.2741T>C p.L914S | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58103234; called by muse, mutect2, varscan2
- GCK | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV67885065; called by muse, mutect2, varscan2
- GOT2 | c.1114C>A p.Q372K | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV55332275; called by muse, mutect2, varscan2
- GPR15 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs573374737, COSV52520907; called by muse, mutect2, varscan2
- GPR68 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs769864285, COSV53176885; called by muse, mutect2, varscan2
- GRID2 | c.1597G>A p.V533M | Missense Mutation (SNP) | VAF 61/106 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1355679013, COSV56227899; called by muse, mutect2, varscan2
- GRM5 | c.2584C>A p.L862I | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.194); catalogued as rs201352068, COSV59614292; called by muse, mutect2, varscan2
- GTF2I | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV60402235; called by muse, mutect2
- H3C8 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 75/155 reads (48%) | catalogued as rs1453083205, COSV59953274; called by muse, mutect2, varscan2
- HCN1 | c.1171G>T p.G391C | Missense Mutation (SNP) | VAF 57/94 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57520200, COSV57522009; called by muse, mutect2, varscan2
- HMCN1 | c.7113G>T p.M2371I | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.921); catalogued as COSV54916025; called by muse, mutect2, varscan2
- HYDIN | c.13486C>T p.R4496C | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1334606358, COSV66640210; called by muse, mutect2, varscan2
- ING3 | c.593A>G p.N198S | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766117424, COSV59951539; called by muse, mutect2, varscan2
- INPP5D | c.2611G>T p.E871* (on ENST00000445964 / NM_001017915.3; = p.E870* on NM_005541.5) | Nonsense Mutation (SNP) | VAF 58/94 reads (62%) | catalogued as COSV64038406; called by muse, mutect2
- IRF2BP2 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.551); catalogued as COSV64015298; called by muse, mutect2, varscan2
- KIAA1109 | c.14091C>G p.I4697M | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs749500125, COSV52681671; called by muse, mutect2, varscan2
- KIF19 | c.2432C>G p.S811C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63429889; called by muse, mutect2, varscan2
- KLF17 | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.273); catalogued as COSV64856648; called by muse, mutect2, varscan2
- KRBA1 | c.252C>A p.D84E | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.594); catalogued as COSV55442649; called by muse, mutect2, varscan2
- LAMA2 | c.6673G>A p.D2225N | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.046); catalogued as COSV70351302; called by muse, mutect2, varscan2
- LENG8 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV58728946; called by muse, mutect2, varscan2
- LILRA4 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT tolerated (0.31); PolyPhen benign (0.153); catalogued as COSV52493235; called by muse, mutect2, varscan2
- LILRA5 | c.563A>T p.Q188L | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV56643708; called by muse, mutect2, varscan2
- LRFN5 | c.2065G>T p.G689W | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV53265345; called by muse, mutect2, varscan2
- LRRC24 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.265); catalogued as COSV52880664; called by muse, mutect2, varscan2
- LRRC7 | c.1522G>A p.D508N (on ENST00000651989 / NM_001370785.2; = p.D475N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as rs1479787904, COSV50506518; called by muse, mutect2, varscan2
- MAP3K21 | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs781171520, COSV64041743; called by muse, mutect2, varscan2
- MARCHF4 | c.860G>T p.C287F | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56106411; called by muse, mutect2, varscan2
- MBP | c.856A>G p.K286E (on ENST00000355994 / NM_001025101.2; = p.K168E on NM_002385.3) | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.138); catalogued as COSV62829817; called by muse, mutect2, varscan2
- MCMBP | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs1393221509, COSV63508467; called by muse, mutect2, varscan2
- MINDY2 | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as COSV57507577; called by muse, mutect2, varscan2
- MORC1 | c.391C>G p.Q131E | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV51724593; called by muse, mutect2, varscan2
- MS4A1 | c.893A>T p.*298Lext*11 | Nonstop Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV61942447; called by muse, mutect2, varscan2
- MSX2 | c.410G>T p.R137M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53327647, COSV99496933; called by muse, mutect2, varscan2
- MYH11 | c.5020A>G p.T1674A | Missense Mutation (SNP) | VAF 83/200 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV55559929; called by muse, mutect2, varscan2
- NBEA | c.6988G>A p.E2330K | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.163); catalogued as COSV59800258; called by muse, mutect2, varscan2
- NDUFB9 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.965); catalogued as rs745392030, COSV52675463; called by muse, mutect2, varscan2
- NFASC | c.2708G>A p.R903K (on ENST00000339876 / NM_001378329.1; = p.R1006K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT tolerated (0.88); PolyPhen benign (0.051); catalogued as COSV58371358; called by muse, mutect2, varscan2
- NMU | c.113-2A>T p.X38_splice | Splice Site (SNP) | VAF 25/70 reads (36%) | catalogued as COSV51700686; called by muse, mutect2, varscan2
- NSD1 | c.4919G>C p.C1640S | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM052307, COSV61779129; called by muse, mutect2, varscan2
- OCIAD2 | c.403G>T p.E135* (on ENST00000508632 / NM_001014446.3; = p.V95= on NM_152398.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 93/165 reads (56%) | catalogued as COSV56717043; called by muse, mutect2, varscan2
- OFD1 | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs779709673, COSV60794378, COSV60797176; called by muse, mutect2, varscan2
- OR1M1 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV70037189; called by muse, mutect2, varscan2
- OR2A25 | c.713C>G p.S238C | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV68717418, COSV68717814; called by muse, mutect2, varscan2
- OR2G3 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60682364, COSV60682738; called by muse, mutect2, varscan2
- OR2J3 | c.520C>A p.H174N | Missense Mutation (SNP) | VAF 116/215 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV65849328; called by muse, mutect2, varscan2
- OR4C15 | c.969G>A p.M323I (on ENST00000314644; = p.M269I on NM_001001920.2) | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.017); catalogued as COSV58954007; called by muse, mutect2, varscan2
- OR4C16 | c.659T>C p.L220S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58942945, COSV58944670; called by muse, mutect2
- OR51E2 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV67807910; called by muse, mutect2, varscan2
- OR52A5 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as rs1327050689, COSV56614024; called by muse, mutect2, varscan2
- OR5H2 | c.945G>C p.*315Yext*? | Nonstop Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV62351286; called by muse, mutect2, varscan2
- PGC | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 81/153 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs572584010, COSV62677449; called by muse, mutect2, varscan2
- PHIP | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 150/306 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV51506921; called by muse, mutect2, varscan2
- PITX3 | c.340C>A p.R114S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64174690; called by mutect2, varscan2
- PJA2 | c.989A>C p.E330A | Missense Mutation (SNP) | VAF 141/159 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV63273663; called by muse, mutect2, varscan2
- PLEKHG4B | c.2665G>C p.E889Q (on ENST00000283426; = p.E1245Q on NM_052909.5) | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV52050524; called by muse, mutect2, varscan2
- POLR3D | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 39/83 reads (47%) | catalogued as COSV60571656; called by muse, mutect2, varscan2
- PRG4 | c.1580C>G p.T527S | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV63355957; called by muse, varscan2
- PRG4 | c.1600A>C p.T534P | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs549460989, COSV63355301; called by muse, varscan2
- PSG2 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 112/186 reads (60%) | catalogued as rs1350459435, COSV61545780; called by muse, varscan2
- RALA | c.115-1G>A p.X39_splice | Splice Site (SNP) | VAF 55/109 reads (50%) | catalogued as COSV50049693; called by muse, mutect2, varscan2
- RASAL2 | c.2612G>A p.R871Q | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.888); catalogued as rs1261065253, COSV62717353; called by muse, mutect2, varscan2
- RCE1 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.265); catalogued as rs750535440, COSV58992794; called by muse, mutect2, varscan2
- RIF1 | c.6497A>G p.Q2166R | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs1236100984, COSV54619841; called by muse, mutect2, varscan2
- RP1L1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs756576372, COSV61446003; called by muse, mutect2, varscan2
- RTEL1 | c.2533G>T p.A845S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV58897193; called by muse, mutect2, varscan2
- RTTN | c.3023C>G p.S1008C | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV55348062; called by muse, mutect2, varscan2
- SALL4 | c.2974A>C p.S992R | Missense Mutation (SNP) | VAF 63/115 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV53854029; called by muse, mutect2, varscan2
- SEL1L | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 207/246 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60921329; called by muse, mutect2, varscan2
- SETBP1 | c.2180G>T p.R727L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56313088, COSV56313647; called by muse, mutect2, varscan2
- SHISAL2A | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68979338; called by muse, mutect2, varscan2
- SLC12A9 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51935147; called by muse, mutect2, varscan2
- SLC22A13 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV61291503; called by muse, mutect2, varscan2
- SLC6A4 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55568171; called by muse, mutect2, varscan2
- SLC8A1 | c.11T>C p.M4T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.692); catalogued as COSV60487604; called by muse, mutect2, varscan2
- SNX32 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57449997; called by mutect2, varscan2
- SPEG | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.542); catalogued as COSV56673898; called by muse, mutect2, varscan2
- SPIB | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV54531725; called by muse, mutect2, varscan2
- SPIRE2 | c.1712T>C p.I571T | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV65556607; called by muse, mutect2, varscan2
- SPPL3 | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV62233204; called by muse, mutect2, varscan2
- SRL | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV68423845; called by muse, mutect2, varscan2
- ST18 | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 88/205 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV52500233; called by muse, mutect2, varscan2
- STAB2 | c.6517C>A p.R2173S | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV66342247; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2297A>G p.Q766R | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV59133496; called by muse, mutect2, varscan2
- SUN5 | c.713del p.P238Qfs*3 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | catalogued as COSV62182850; called by mutect2, pindel
- TBK1 | c.2073G>C p.K691N | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as CD166593, COSV59156669; called by muse, mutect2, varscan2
- TNIK | c.3029A>G p.E1010G | Missense Mutation (SNP) | VAF 142/255 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV52687410; called by muse, mutect2, varscan2
- TPSG1 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as COSV52356169; called by muse, mutect2, varscan2
- TPTE | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1353676205; called by muse, mutect2
- TRAF3 | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 82/102 reads (80%) | catalogued as COSV61023812, COSV61026222; called by muse, mutect2, varscan2
- TRIML1 | c.183G>C p.E61D | Missense Mutation (SNP) | VAF 85/146 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV60195392; called by muse, mutect2, varscan2
- TTN | c.48570A>T p.Q16190H (on ENST00000591111; = p.Q8766H on NM_003319.4) | Missense Mutation (SNP) | VAF 57/257 reads (22%) | PolyPhen benign (0.421); catalogued as COSV60176335; called by muse, mutect2, varscan2
- UCP1 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV53768102; called by muse, mutect2, varscan2
- VGF | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV50800870, COSV50802024; called by muse, mutect2, varscan2
- VPS29 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV62195141; called by muse, mutect2, varscan2
- WDTC1 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 39/72 reads (54%) | catalogued as COSV60089206; called by muse, mutect2, varscan2
- ZMIZ1 | c.863T>C p.V288A | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); catalogued as COSV100566213; called by muse, mutect2, varscan2
- ZNF208 | c.1306T>A p.W436R | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.17); catalogued as COSV68109372; called by muse, mutect2
- ZNF44 | c.1716G>T p.R572S (on ENST00000356109 / NM_001164276.2; = p.R524S on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV61135788; called by muse, mutect2, varscan2
- ZNF776 | c.1507C>G p.L503V | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs778742456, COSV57815795; called by muse, mutect2, varscan2
- ZNF79 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV61071336; called by muse, mutect2, varscan2
- ZPBP | c.287T>A p.I96K | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs746792066, COSV50428305; called by muse, mutect2, varscan2
- ZSCAN18 | c.1358G>T p.S453I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV53734724; called by muse, mutect2, varscan2
- ASIC1 | c.1491_1492del p.C497* | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- DUSP10 | c.503_528del p.P168Lfs*19 | Frame Shift Del (DEL) | VAF 31/102 reads (30%) | called by mutect2, pindel, varscan2
- LRIT2 | c.1453del p.A485Qfs*51 | Frame Shift Del (DEL) | VAF 25/73 reads (34%) | called by mutect2, pindel, varscan2
- MARCHF11 | c.559del p.R187Dfs*15 | Frame Shift Del (DEL) | VAF 32/158 reads (20%) | called by mutect2, pindel, varscan2
- OR1S2 | c.976del p.*326delext*? | Frame Shift Del (DEL) | VAF 28/148 reads (19%) | called by pindel, varscan2
- OR1S2 | c.970T>C p.S324P | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, varscan2
- PBX1 | c.376_384del p.S126_A128del | In Frame Del (DEL) | VAF 5/30 reads (17%) | called by pindel, varscan2*
- PPP1R3C | c.627dup p.G210Wfs*4 | Frame Shift Ins (INS) | VAF 55/130 reads (42%) | called by mutect2, pindel, varscan2
- PRSS35 | c.186_187del p.C62Wfs*15 | Frame Shift Del (DEL) | VAF 44/174 reads (25%) | called by pindel, varscan2
- TACR1 | c.851dup p.Q285Afs*26 | Frame Shift Ins (INS) | VAF 86/175 reads (49%) | called by mutect2, pindel, varscan2
- ABCC8 | c.1170A>G p.A390= | Silent (SNP) | VAF 23/135 reads (17%) | catalogued as COSV56853517; called by muse, mutect2, varscan2
- CEP57 | c.471C>T p.A157= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs753111395, COSV57687292; called by muse, mutect2, varscan2
- CGN | c.780C>A p.L260= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV54967882, COSV54971629; called by muse, mutect2, varscan2
- CHD7 | c.1245G>A p.P415= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as rs745900311, COSV71107974; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLIP2 | c.1230C>T p.A410= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs564040624, COSV56281804; called by muse, mutect2, varscan2
- CNTRL | c.3360A>T p.R1120= | Silent (SNP) | VAF 38/40 reads (95%) | catalogued as COSV53049739; called by muse, mutect2, varscan2
- CUL5 | c.339A>G p.Q113= | Silent (SNP) | VAF 46/74 reads (62%) | catalogued as COSV67608694, COSV67609464; called by muse, varscan2
- DNAH11 | c.393G>A p.K131= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV60965739; called by muse, mutect2, varscan2
- DNMBP | c.393G>T p.R131= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV60628740; called by muse, mutect2, varscan2
- EXPH5 | c.1179A>T p.S393= | Silent (SNP) | VAF 135/240 reads (56%) | catalogued as rs755374417, COSV56204817, COSV56207919; called by muse, mutect2, varscan2
- FAM187B | c.228C>T p.P76= | Silent (SNP) | VAF 48/86 reads (56%) | catalogued as rs146665895; called by muse, varscan2
- FAM187B | c.144G>T p.G48= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as COSV61201515; called by muse, varscan2
- FAM20C | c.639C>G p.L213= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs1430301262, COSV58235222; called by muse, mutect2, varscan2
- FAT1 | c.13719A>G p.E4573= | Silent (SNP) | VAF 25/27 reads (93%) | catalogued as COSV71674976; called by muse, mutect2, varscan2
- FLNA | c.1290A>G p.V430= | Silent (SNP) | VAF 36/40 reads (90%) | catalogued as COSV61046859; called by muse, mutect2, varscan2
- GALNT13 | c.507C>T p.Y169= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs187976407; called by muse, mutect2, varscan2
- GCDH | c.282G>A p.R94= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as COSV53435464, COSV99322378; called by muse, mutect2, varscan2
- GRIN2A | c.3000G>A p.V1000= | Silent (SNP) | VAF 55/115 reads (48%) | catalogued as COSV58043640; called by muse, mutect2, varscan2
- HOXD12 | c.438G>T p.T146= | Silent (SNP) | VAF 46/67 reads (69%) | catalogued as rs375386525, COSV66832765; called by muse, mutect2, varscan2
- KLHL6 | c.1692C>T p.G564= | Silent (SNP) | VAF 25/216 reads (12%) | catalogued as rs1329365469, COSV100384495, COSV58067762; called by muse, mutect2, varscan2
- LRFN5 | c.1191C>T p.I397= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV53265334; called by muse, mutect2, varscan2
- LRRTM3 | c.30C>T p.S10= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs763055807, COSV63662783, COSV63668137; called by muse, mutect2, varscan2
- MED14 | c.1878G>A p.K626= | Silent (SNP) | VAF 27/28 reads (96%) | catalogued as COSV61357630; called by muse, mutect2, varscan2
- MRPL16 | c.300C>A p.G100= | Silent (SNP) | VAF 65/109 reads (60%) | catalogued as COSV55699333; called by muse, mutect2, varscan2
- MRPL22 | c.93A>T p.S31= | Silent (SNP) | VAF 51/63 reads (81%) | catalogued as COSV54558889; called by muse, mutect2, varscan2
- MSMB | c.318C>A p.T106= | Silent (SNP) | VAF 72/157 reads (46%) | called by muse, mutect2, varscan2
- NDUFA9 | c.210C>T p.V70= | Silent (SNP) | VAF 49/154 reads (32%) | catalogued as COSV56930347; called by muse, mutect2, varscan2
- OR2T34 | c.334C>T p.L112= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV100170369, COSV60901068; called by muse, mutect2, varscan2
- OR4C16 | c.660G>A p.L220= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs370836583, COSV58942958; called by muse, mutect2
- OTULINL | c.1041C>T p.N347= | Silent (SNP) | VAF 35/151 reads (23%) | catalogued as rs200729060, COSV57035076; called by muse, mutect2, varscan2
- PAQR8 | c.786C>T p.F262= | Silent (SNP) | VAF 49/104 reads (47%) | catalogued as COSV62443085; called by muse, mutect2, varscan2
- PAX3 | c.912G>C p.T304= | Silent (SNP) | VAF 249/346 reads (72%) | catalogued as COSV60587194, COSV60589945; called by muse, mutect2, varscan2
- PDHX | c.78A>G p.V26= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV53507633; called by muse, mutect2, varscan2
- PFKM | c.969A>G p.A323= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as COSV56658829; called by muse, mutect2, varscan2
- PHF20 | c.1629G>A p.K543= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as COSV59187124; called by muse, mutect2, varscan2
- PPP1R13L | c.2445C>T p.F815= | Silent (SNP) | VAF 49/78 reads (63%) | catalogued as rs1568552740, COSV62909028; called by muse, mutect2, varscan2
- PROKR2 | c.198C>T p.V66= | Silent (SNP) | VAF 72/129 reads (56%) | catalogued as COSV54087638, COSV99450701; called by muse, mutect2, varscan2
- RAP1GAP | c.1221C>A p.S407= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV51574758; called by muse, mutect2, varscan2
- RASAL3 | c.2004G>A p.L668= | Silent (SNP) | VAF 22/248 reads (9%) | catalogued as COSV54609544; called by muse, mutect2
- RDH13 | c.711G>T p.L237= (on ENST00000415061 / NM_001145971.2; = p.L166= on NM_138412.4) | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as COSV52561680; called by muse, mutect2, varscan2
- SDK2 | c.5812C>T p.L1938= | Silent (SNP) | VAF 56/112 reads (50%) | catalogued as rs978695707, COSV66190689; called by muse, mutect2, varscan2
- SHROOM4 | c.4134G>T p.L1378= | Silent (SNP) | VAF 33/35 reads (94%) | catalogued as COSV56792590; called by muse, mutect2, varscan2
- TBC1D16 | c.2199G>A p.E733= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs1260773879, COSV59988937; called by muse, mutect2, varscan2
- TEP1 | c.4539G>T p.T1513= | Silent (SNP) | VAF 66/76 reads (87%) | catalogued as COSV52995692; called by muse, mutect2, varscan2
- TRIM5 | c.78G>A p.L26= | Silent (SNP) | VAF 60/145 reads (41%) | catalogued as COSV59900881; called by muse, mutect2, varscan2
- UNC45B | c.1044T>A p.T348= | Silent (SNP) | VAF 173/322 reads (54%) | catalogued as COSV52097871; called by muse, mutect2, varscan2
- ZFP30 | c.336T>C p.C112= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV63622799; called by muse, mutect2, varscan2
- ZNF700 | c.213C>T p.N71= | Silent (SNP) | VAF 101/147 reads (69%) | catalogued as COSV54313973; called by muse, mutect2, varscan2
- DNM1P46 | n.1014T>A | RNA (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- H2BC4 | c.-1G>A | 5'UTR (SNP) | VAF 58/122 reads (48%) | catalogued as rs772024840, COSV100019750, COSV58417612; called by muse, mutect2, varscan2
- HOXB9 | c.-2G>A | 5'UTR (SNP) | VAF 39/99 reads (39%) | catalogued as COSV100239547; called by muse, mutect2, varscan2
- MAD1L1 | c.472-1432A>T | Intron (SNP) | VAF 18/28 reads (64%) | catalogued as COSV99766465; called by muse, mutect2
- SEMA5A | c.-1C>A | 5'UTR (SNP) | VAF 42/222 reads (19%) | catalogued as COSV101228464; called by muse, mutect2, varscan2
- SNORD116-20 | n.84C>T | RNA (SNP) | VAF 28/100 reads (28%) | called by muse, mutect2, varscan2
